Somatic mutation profile of tumor specimen C3N-01166-02 (aliquot CPT0093980010_1) from CPTAC case C3N-01166, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 62.7 years (22,892 days).
Specimen C3N-01166-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 763b671f-6d21-4cc7-ad02-6354eb2c346c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01166-31 (Blood Derived Normal), aliquot CPT0094020002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ca00c210-42e8-43f5-99f8-3f503bacbbb7

The open-access MAF lists 33 somatic variants for this specimen: 22 protein-altering or splice-affecting, 7 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 7, Nonsense Mutation 3, Intron 2, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 34/598 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- TP53 | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 67/865 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs587778720, CM004906, CM022474, COSV52665093, COSV52668963, COSV52693072; ClinVar: drug response / pathogenic / likely pathogenic / not provided; called by muse, mutect2
- ABCA3 | c.3319G>A p.A1107T | Missense Mutation (SNP) | VAF 78/1004 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.227); catalogued as rs140114428, COSV57053333; called by muse, mutect2
- ADAMTS10 | c.2026G>A p.E676K | Missense Mutation (SNP) | VAF 46/936 reads (5%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); catalogued as rs1555738275, COSV54353387; called by muse, mutect2
- ARHGEF10 | c.2945C>T p.A982V (on ENST00000398564; = p.A957V on NM_014629.4) | Missense Mutation (SNP) | VAF 42/615 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs774662836; called by muse, mutect2
- FRMPD3 | c.3220C>T p.R1074W | Missense Mutation (SNP) | VAF 26/380 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.245); catalogued as rs770880383; called by muse, mutect2
- HP1BP3 | c.80C>T p.A27V | Missense Mutation (SNP) | VAF 38/606 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as rs1402201010; called by muse, mutect2
- PABPC3 | c.61G>A p.D21N | Missense Mutation (SNP) | VAF 65/391 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as COSV55796483; called by muse, mutect2, varscan2
- PIK3AP1 | c.1915C>T p.R639* | Nonsense Mutation (SNP) | VAF 38/398 reads (10%) | catalogued as COSV59531058; called by muse, mutect2
- PRAMEF1 | c.215C>T p.T72M | Missense Mutation (SNP) | VAF 62/1132 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.018); catalogued as rs149382773, COSV100179428; called by muse, mutect2
- SDHB | c.167C>G p.P56R | Missense Mutation (SNP) | VAF 47/786 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as CM061958, COSV100973362; called by muse, mutect2
- SIPA1L2 | c.3988G>T p.E1330* | Nonsense Mutation (SNP) | VAF 14/214 reads (7%) | catalogued as COSV53388390; called by muse, mutect2
- SLC9A1 | c.1894C>T p.R632C | Missense Mutation (SNP) | VAF 27/692 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1309855858, COSV56053097; called by muse, mutect2
- SPATA2 | c.652C>T p.R218W | Missense Mutation (SNP) | VAF 38/582 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs570040800; called by muse, mutect2
- ZNF257 | c.653G>A p.R218Q | Missense Mutation (SNP) | VAF 27/313 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs755947286, COSV71306204; called by muse, mutect2
- ALOX12 | c.1858C>A p.P620T | Missense Mutation (SNP) | VAF 21/300 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.029); called by muse, mutect2
- HEATR1 | c.4391T>A p.M1464K | Missense Mutation (SNP) | VAF 21/300 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.238); called by muse, mutect2
- OR5D18 | c.775C>A p.L259I | Missense Mutation (SNP) | VAF 27/382 reads (7%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.573); called by muse, mutect2
- PRR36 | c.2083G>C p.A695P | Missense Mutation (SNP) | VAF 52/616 reads (8%) | SIFT tolerated, low confidence (0.45); called by muse, mutect2
- TSHZ2 | c.1772C>T p.P591L | Missense Mutation (SNP) | VAF 42/659 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.058); called by muse, mutect2
- UBR4 | c.10678C>T p.Q3560* | Nonsense Mutation (SNP) | VAF 29/460 reads (6%) | called by muse, mutect2
- WDR89 | c.989A>C p.N330T | Missense Mutation (SNP) | VAF 23/266 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2
- ALOX5AP | c.189G>A p.A63= | Silent (SNP) | VAF 38/674 reads (6%) | catalogued as rs144243124; called by muse, mutect2
- DZANK1 | c.1204C>T p.L402= (on ENST00000262547 / NM_001099407.1; = p.L203= on NM_018152.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 29/424 reads (7%) | called by muse, mutect2
- EPB42 | c.1101G>A p.P367= (on ENST00000441366 / NM_001114134.2; = p.P397= on NM_000119.3) | Silent (SNP) | VAF 60/761 reads (8%) | catalogued as rs1449860988, COSV55751408; called by muse, mutect2
- GJA1 | c.231C>T p.F77= | Silent (SNP) | VAF 36/684 reads (5%) | called by muse, mutect2
- HBD | c.405G>A p.V135= | Silent (SNP) | VAF 49/1025 reads (5%) | called by muse, mutect2
- MSL2 | c.1461C>T p.R487= | Silent (SNP) | VAF 60/959 reads (6%) | catalogued as rs746093243, COSV53859033; called by muse, mutect2
- OTUD5 | c.1359G>A p.P453= | Silent (SNP) | VAF 48/914 reads (5%) | catalogued as rs782068554; called by muse, mutect2
- FAM205BP | n.287G>A | RNA (SNP) | VAF 23/424 reads (5%) | catalogued as rs749043515; called by muse, mutect2
- LAT | chr16:28984850 C>T | 5'Flank (SNP) | VAF 36/506 reads (7%) | catalogued as rs770318081; called by muse, mutect2
- NDUFA5 | c.66+234G>C | Intron (SNP) | VAF 18/682 reads (3%) | called by muse, mutect2
- NKD1 | c.193-1592G>A | Intron (SNP) | VAF 8/126 reads (6%) | catalogued as rs1362079749; called by muse, mutect2
